Somatic mutation profile of tumor specimen TCGA-CJ-4920-01A (aliquot TCGA-CJ-4920-01A-01D-1429-08) from TCGA case TCGA-CJ-4920, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 64.8 years (23,656 days).
Specimen TCGA-CJ-4920-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f520e9bd-1a5b-451c-8317-8d4e931d5638.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4920-11A (Solid Tissue Normal), aliquot TCGA-CJ-4920-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d2a12f0-5a7b-4178-a8d3-c2d447c0b33f

The open-access MAF lists 152 somatic variants for this specimen: 124 protein-altering or splice-affecting, 25 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 25, Frame Shift Del 19, Nonsense Mutation 5, Frame Shift Ins 4, Intron 3, Splice Site 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 4/8 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs5030826, CM941362, CM941363, CM941364, COSV56543026, COSV56543035, COSV56543220, COSV56562588; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.3917C>A p.P1306Q | Missense Mutation (SNP) | VAF 96/373 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV59386261; called by muse, mutect2, varscan2
- ABL1 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59331123; called by muse, mutect2, varscan2
- ADAMTS2 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs1428546169, COSV51077498; called by muse, mutect2, varscan2
- ADAR | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 90/276 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV52715008; called by muse, mutect2, varscan2
- ADGRD1 | c.2176G>T p.V726F | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV55444711; called by muse, mutect2, varscan2
- ALDH1B1 | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.285); catalogued as COSV66619652, COSV66619678; called by muse, varscan2
- ALG13 | c.1367T>A p.V456E | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52638642; called by muse, mutect2, varscan2
- ANKRD50 | c.68T>G p.F23C | Missense Mutation (SNP) | VAF 105/359 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV72385519; called by muse, mutect2, varscan2
- APOBEC1 | c.686T>C p.I229T | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV57548857; called by muse, mutect2, varscan2
- ARID5A | c.1699C>A p.L567I | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV62591104; called by muse, mutect2, varscan2
- ARMCX5 | c.757A>T p.T253S | Missense Mutation (SNP) | VAF 78/304 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV55766525; called by muse, mutect2, varscan2
- ARMCX6 | c.251C>A p.T84N | Missense Mutation (SNP) | VAF 75/269 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV62680733; called by muse, mutect2, varscan2
- ATP10D | c.2116A>T p.N706Y | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.317); catalogued as COSV56707199; called by muse, mutect2, varscan2
- ATP1A4 | c.2774A>T p.Q925L | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV63626428; called by muse, mutect2, varscan2
- BCL11B | c.2600G>A p.S867N (on ENST00000357195 / NM_001282237.2; = p.S796N on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61735428; called by muse, mutect2
- BRINP2 | c.1505T>C p.F502S | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV64177382; called by muse, mutect2, varscan2
- CAMTA2 | c.3471-1G>A p.X1157_splice | Splice Site (SNP) | VAF 36/113 reads (32%) | catalogued as COSV52777336; called by muse, mutect2, varscan2
- CASQ2 | c.1064C>G p.A355G | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.677); catalogued as COSV54770258; called by muse, mutect2, varscan2
- CCT8 | c.123A>T p.Q41H | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV54503914; called by muse, mutect2, varscan2
- CDH6 | c.788A>T p.D263V | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV54069323; called by muse, mutect2, varscan2
- CDKL5 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 96/474 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as rs372629988, COSV66110166; ClinVar: likely benign; called by muse, varscan2
- CDX1 | c.628C>G p.R210G | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV51568081; called by muse, varscan2
- CEBPG | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV52287389; called by muse, mutect2, varscan2
- CEP131 | c.2016G>T p.Q672H (on ENST00000269392 / NM_001319228.2; = p.Q669H on NM_014984.4) | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV53952935; called by muse, mutect2
- COL6A3 | c.4196G>T p.S1399I | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs1184183405, COSV55088688; called by muse, mutect2, varscan2
- COQ5 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 181/565 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.085); catalogued as rs752705524, COSV56018980; called by muse, mutect2, varscan2
- CRYGB | c.253C>A p.H85N | Missense Mutation (SNP) | VAF 94/314 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as COSV53680160; called by muse, mutect2, varscan2
- CYP19A1 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1237240555, COSV53059215; called by muse, mutect2, varscan2
- CYP2C19 | c.953A>C p.E318A | Missense Mutation (SNP) | VAF 64/236 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV64907688; called by muse, mutect2, varscan2
- DDX39B | c.239T>C p.I80T | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV63331356; called by muse, mutect2, varscan2
- DOCK7 | c.4414G>T p.D1472Y (on ENST00000635253 / NM_001367561.1; = p.D1441Y on NM_033407.3) | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV52004492; called by muse, mutect2, varscan2
- EFR3A | c.95T>G p.L32R | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54457007; called by muse, mutect2, varscan2
- EIF2AK2 | c.465A>C p.Q155H | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.47); catalogued as COSV51796240; called by muse, mutect2
- EIF4G1 | c.4556A>G p.Q1519R (on ENST00000346169 / NM_198241.3; = p.Q1324R on NM_004953.5) | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.218); catalogued as COSV59990791; called by muse, mutect2, varscan2
- ELMOD3 | c.588G>T p.W196C | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59772599, COSV59772957; called by muse, mutect2, varscan2
- EMILIN2 | c.589A>G p.T197A | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as COSV54423397, COSV54423652; called by muse, varscan2
- EML5 | c.1049G>C p.R350T | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV61345361; called by muse, mutect2, varscan2
- EPB41L4B | c.1525C>G p.Q509E | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV65803027; called by muse, mutect2, varscan2
- F7 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as CM010256; called by muse, mutect2
- FAM153B | c.608C>T p.S203F (on ENST00000253490; = p.S126F on NM_001265615.1) | Missense Mutation (SNP) | VAF 30/756 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV53686401; called by muse, mutect2
- FN1 | c.1036+1del p.X346_splice | Splice Site (DEL) | VAF 150/601 reads (25%) | catalogued as COSV100117102; called by mutect2, pindel, varscan2
- FRYL | c.3474G>C p.L1158F | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV51946541; called by muse, mutect2, varscan2
- GABRE | c.1432T>A p.Y478N | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.952); catalogued as COSV64819565; called by muse, mutect2, varscan2
- GNA13 | c.1123A>C p.M375L | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.881); catalogued as COSV71474717; called by muse, mutect2, varscan2
- GPATCH2 | c.1237A>G p.R413G | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.631); catalogued as COSV65130901; called by muse, mutect2, varscan2
- GSPT1 | c.1051G>A p.V351I (on ENST00000420576 / NM_001130007.2; = p.V489I on NM_002094.4) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV70452651; called by muse, mutect2, varscan2
- HIVEP1 | c.6621del p.S2208Qfs*19 | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | catalogued as rs34103769; called by mutect2, pindel, varscan2
- HJURP | c.446A>T p.K149I | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV64978760; called by muse, mutect2, varscan2
- HSP90AA1 | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53488551, COSV99355590; called by muse, mutect2, varscan2
- HSPH1 | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.366); catalogued as COSV60711346; called by muse, mutect2, varscan2
- HTR2C | c.220G>C p.V74L | Missense Mutation (SNP) | VAF 82/291 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV52209771; called by muse, mutect2, varscan2
- INTS8 | c.1280A>C p.N427T | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.013); catalogued as COSV58250273; called by muse, mutect2, varscan2
- IRAK1 | c.1750C>A p.Q584K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as rs1212571352, COSV64110850; called by muse, mutect2, varscan2
- KIF27 | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as COSV52827539, COSV52831102; called by muse, mutect2, varscan2
- LONRF3 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.082); catalogued as COSV59151984; called by muse, mutect2, varscan2
- LRP2 | c.3158A>T p.D1053V | Missense Mutation (SNP) | VAF 156/553 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55552295; called by muse, mutect2, varscan2
- MAGEE1 | c.2146G>T p.E716* | Nonsense Mutation (SNP) | VAF 26/66 reads (39%) | catalogued as COSV63910111; called by muse, mutect2, varscan2
- MAP3K1 | c.953T>G p.L318* | Nonsense Mutation (SNP) | VAF 40/156 reads (26%) | catalogued as COSV68123519; called by muse, mutect2, varscan2
- MARS2 | c.287G>C p.G96A | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56571253; called by muse, mutect2, varscan2
- MFN1 | c.1646C>A p.S549* | Nonsense Mutation (SNP) | VAF 33/131 reads (25%) | catalogued as COSV54939537; called by muse, mutect2, varscan2
- MKRN3 | c.364T>A p.S122T | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV58809806; called by muse, mutect2, varscan2
- MTMR10 | c.1882G>C p.E628Q | Missense Mutation (SNP) | VAF 14/498 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV58728135; called by muse, mutect2
- MYH14 | c.1594C>G p.L532V | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV51817146; called by muse, mutect2, varscan2
- N4BP2L2 | c.845T>C p.L282P | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV57228326; called by muse, mutect2, varscan2
- NLRP4 | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56713184; called by muse, mutect2, varscan2
- NOTCH2 | c.5714C>A p.A1905D | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV56690870; called by muse, mutect2, varscan2
- NPHS1 | c.651T>G p.C217W | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62287709; called by muse, mutect2, varscan2
- OGFOD1 | c.7G>C p.G3R | Missense Mutation (SNP) | VAF 68/273 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV55859865; called by muse, mutect2, varscan2
- OGG1 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV57352870; called by muse, mutect2, varscan2
- OR52L1 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV59986970; called by muse, mutect2, varscan2
- PAPPA | c.2093A>T p.D698V | Missense Mutation (SNP) | VAF 92/304 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV60282736; called by muse, varscan2
- PCNX2 | c.2370G>C p.Q790H | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.459); catalogued as rs1264231349, COSV50799263; called by muse, mutect2
- PHTF2 | c.539G>A p.G180E (on ENST00000248550 / NM_001366089.1; = p.G142E on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50326305; called by muse, mutect2
- PMP22 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.551); catalogued as COSV56602060; called by muse, mutect2, varscan2
- PRDM12 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs750758387, COSV53390467; called by muse, mutect2, varscan2
- PTK7 | c.1536G>T p.Q512H | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57848495; called by muse, mutect2, varscan2
- PTPN3 | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 66/206 reads (32%) | catalogued as rs1240258245, COSV52705620; called by muse, varscan2
- PTPRZ1 | c.1585C>G p.H529D | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV66436065; called by muse, mutect2, varscan2
- RAD51 | c.815A>T p.Q272L | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV51111621; called by muse, mutect2, varscan2
- RIMS4 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); catalogued as COSV65719680; called by muse, mutect2, varscan2
- RPH3AL | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV58742267; called by muse, mutect2, varscan2
- RYR2 | c.938A>T p.N313I | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs980734364, COSV63684157; called by muse, mutect2
- SBF1 | c.1466T>C p.V489A | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.435); catalogued as COSV62367454; called by muse, mutect2, varscan2
- SEMA4A | c.326A>G p.K109R | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV61772644; called by muse, mutect2, varscan2
- SETD2 | c.5586del p.K1863Sfs*2 | Frame Shift Del (DEL) | VAF 42/182 reads (23%) | catalogued as COSV57447281; called by mutect2, pindel, varscan2
- SFXN4 | c.277_278insA p.L93Hfs*68 | Frame Shift Ins (INS) | VAF 80/276 reads (29%) | catalogued as COSV100341220; called by mutect2, pindel, varscan2
- SHCBP1L | c.954T>G p.I318M | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV62354838; called by muse, mutect2, varscan2
- SLC16A4 | c.1453A>G p.S485G | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.005); catalogued as rs1272749493, COSV63916515; called by muse, mutect2, varscan2
- SLC49A3 | c.976G>A p.A326T (on ENST00000404286 / NM_001294341.2; = p.A325T on NM_032219.4) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as COSV59140223; called by muse, mutect2, varscan2
- SLC4A4 | c.1212G>T p.K404N (on ENST00000264485 / NM_001098484.3; = p.K360N on NM_003759.4) | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV52623715; called by muse, mutect2
- SLC51A | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1177148031, COSV56351641; called by muse, mutect2, varscan2
- ST6GAL2 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 54/166 reads (33%) | PolyPhen benign (0.005); catalogued as COSV64526997; called by muse, mutect2, varscan2
- SULF1 | c.1051C>G p.P351A | Missense Mutation (SNP) | VAF 122/476 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV52680734; called by muse, mutect2, varscan2
- TANC2 | c.5008G>A p.D1670N | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.971); catalogued as COSV67329679; called by muse, mutect2, varscan2
- THAP9 | c.1575C>G p.N525K | Missense Mutation (SNP) | VAF 85/325 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.262); catalogued as COSV56356386; called by muse, mutect2, varscan2
- TMEM245 | c.851A>C p.N284T | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV65822627; called by muse, mutect2, varscan2
- TMPRSS15 | c.1903T>A p.Y635N | Missense Mutation (SNP) | VAF 117/395 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53039430; called by muse, mutect2, varscan2
- TRPM6 | c.1025A>C p.Q342P | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV62509532; called by muse, mutect2, varscan2
- TTC12 | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 56/216 reads (26%) | catalogued as COSV59097744; called by muse, mutect2, varscan2
- TTN | c.39521G>A p.G13174E (on ENST00000591111; = p.G5750E on NM_003319.4) | Missense Mutation (SNP) | VAF 115/460 reads (25%) | PolyPhen probably damaging (0.959); catalogued as rs1157011423, COSV60041104, COSV60280736; called by muse, mutect2, varscan2
- UROC1 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 92/372 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52032852; called by muse, mutect2, varscan2
- YME1L1 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 134/439 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV58759351; called by muse, varscan2
- ZSWIM8 | c.3172T>C p.S1058P (on ENST00000605216 / NM_001242487.2; = p.S1063P on NM_015037.3) | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55214360; called by muse, mutect2, varscan2
- ARFGEF1 | c.4132del p.W1378Gfs*2 | Frame Shift Del (DEL) | VAF 28/148 reads (19%) | called by mutect2, pindel, varscan2
- BCKDK | c.1030del p.R344Gfs*160 | Frame Shift Del (DEL) | VAF 22/117 reads (19%) | called by mutect2, pindel, varscan2
- BTG3 | c.558_579del p.H186Qfs*36 | Frame Shift Del (DEL) | VAF 29/143 reads (20%) | called by mutect2, pindel, varscan2
- CCSER2 | c.145del p.S49Vfs*44 | Frame Shift Del (DEL) | VAF 45/159 reads (28%) | called by mutect2, pindel, varscan2
- DOP1B | c.3577_3578del p.S1193Qfs*63 | Frame Shift Del (DEL) | VAF 24/113 reads (21%) | called by pindel, varscan2
- DPPA2 | c.70_76del p.V24* | Frame Shift Del (DEL) | VAF 72/284 reads (25%) | called by mutect2, pindel, varscan2
- EXO5 | c.558_567del p.Y186* | Frame Shift Del (DEL) | VAF 47/227 reads (21%) | called by mutect2, pindel, varscan2
- KIAA1549L | c.1650del p.S551Hfs*97 (on ENST00000321505; = p.S848Hfs*97 on NM_012194.3) | Frame Shift Del (DEL) | VAF 47/179 reads (26%) | called by mutect2, pindel, varscan2
- MAP3K20 | c.2346del p.A783Pfs*49 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- NALCN | c.1886del p.L629Yfs*16 | Frame Shift Del (DEL) | VAF 128/549 reads (23%) | called by mutect2, pindel, varscan2
- NRAP | c.391_400del p.N131Afs*11 | Frame Shift Del (DEL) | VAF 53/402 reads (13%) | called by pindel, varscan2
- PBRM1 | c.1742_1747delinsA p.A581Efs*19 | Frame Shift Del (DEL) | VAF 36/102 reads (35%) | called by pindel, varscan2*
- PRTG | c.1088del p.N363Mfs*19 | Frame Shift Del (DEL) | VAF 53/208 reads (25%) | called by mutect2, pindel, varscan2
- PTPN18 | c.771del p.F258Sfs*10 | Frame Shift Del (DEL) | VAF 40/192 reads (21%) | called by mutect2, pindel, varscan2
- SART3 | c.1609dup p.R537Kfs*5 (on ENST00000228284; = p.R519Kfs*5 on NM_014706.4) | Frame Shift Ins (INS) | VAF 120/442 reads (27%) | called by mutect2, pindel, varscan2
- SLF2 | c.704_705delinsT p.K235Ifs*6 | Frame Shift Del (DEL) | VAF 43/177 reads (24%) | called by pindel, varscan2*
- SMC1A | c.2202del p.K734Nfs*8 | Frame Shift Del (DEL) | VAF 41/157 reads (26%) | called by mutect2, pindel, varscan2
- ST6GALNAC3 | c.909dup p.L304Ifs*16 | Frame Shift Ins (INS) | VAF 55/239 reads (23%) | called by mutect2, pindel, varscan2
- WDR72 | c.2504_2508dup p.D837Mfs*7 | Frame Shift Ins (INS) | VAF 52/197 reads (26%) | called by mutect2, pindel, varscan2
- ZNF597 | c.472_488del p.C158Kfs*22 | Frame Shift Del (DEL) | VAF 77/412 reads (19%) | called by mutect2, pindel, varscan2
- ACTR3B | c.1140A>G p.G380= | Silent (SNP) | VAF 4/76 reads (5%) | catalogued as COSV55448481; called by muse, mutect2
- AHCTF1 | c.1635C>A p.L545= (on ENST00000366508; = p.L519= on NM_015446.5) | Silent (SNP) | VAF 53/226 reads (23%) | catalogued as COSV58249608; called by muse, mutect2, varscan2
- AMER3 | c.2091A>T p.P697= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV58466616; called by muse, mutect2, varscan2
- ANKK1 | c.1341C>T p.L447= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs1396869932, COSV58271772; called by muse, mutect2, varscan2
- ATP13A1 | c.822G>T p.V274= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV52285520; called by muse, mutect2, varscan2
- AXIN1 | c.462C>T p.G154= | Silent (SNP) | VAF 63/223 reads (28%) | catalogued as COSV51987033; called by muse, mutect2, varscan2
- CCDC116 | c.1101C>T p.R367= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV53040432; called by muse, mutect2, varscan2
- DUS2 | c.21T>A p.S7= | Silent (SNP) | VAF 77/268 reads (29%) | catalogued as COSV62708404; called by muse, mutect2, varscan2
- ENPP3 | c.729A>G p.E243= | Silent (SNP) | VAF 42/136 reads (31%) | catalogued as COSV62954174; called by muse, mutect2, varscan2
- EPHX1 | c.858G>A p.K286= | Silent (SNP) | VAF 86/253 reads (34%) | catalogued as rs1166841987, COSV55300522; called by muse, mutect2, varscan2
- ETV3 | c.105C>T p.I35= | Silent (SNP) | VAF 47/181 reads (26%) | catalogued as COSV58748013; called by muse, mutect2, varscan2
- GRAMD1A | c.342G>T p.L114= | Silent (SNP) | VAF 67/250 reads (27%) | catalogued as COSV58766966; called by muse, mutect2, varscan2
- LIPE | c.786C>T p.F262= | Silent (SNP) | VAF 20/268 reads (7%) | catalogued as COSV54922781; called by muse, mutect2
- MCCC1 | c.1263G>C p.R421= | Silent (SNP) | VAF 53/207 reads (26%) | catalogued as COSV55606527, COSV55608633; called by muse, mutect2, varscan2
- NCAPG2 | c.2722C>A p.R908= | Silent (SNP) | VAF 106/459 reads (23%) | catalogued as COSV51987370; called by muse, mutect2, varscan2
- NR3C2 | c.1278A>C p.P426= | Silent (SNP) | VAF 70/264 reads (27%) | catalogued as COSV60990056; called by muse, mutect2, varscan2
- PDIA2 | c.1458T>A p.T486= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV51987025; called by muse, mutect2, varscan2
- QSER1 | c.1833C>T p.I611= (on ENST00000399302; = p.I740= on NM_001076786.3) | Silent (SNP) | VAF 59/258 reads (23%) | catalogued as COSV67900465, COSV67902032; called by muse, mutect2, varscan2
- SCN11A | c.735C>A p.A245= | Silent (SNP) | VAF 52/129 reads (40%) | catalogued as COSV56569806; called by muse, mutect2, varscan2
- SNW1 | c.1326T>C p.D442= | Silent (SNP) | VAF 42/218 reads (19%) | catalogued as COSV53174120; called by muse, mutect2, varscan2
- SULT2A1 | c.379T>C p.L127= | Silent (SNP) | VAF 66/244 reads (27%) | catalogued as COSV55764860; called by muse, mutect2, varscan2
- TAFA4 | c.291C>G p.S97= | Silent (SNP) | VAF 94/258 reads (36%) | catalogued as COSV55137419, COSV99807655; called by muse, mutect2, varscan2
- TECRL | c.177C>T p.H59= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV67086994; called by muse, mutect2
- TFDP3 | c.405C>T p.G135= | Silent (SNP) | VAF 46/156 reads (29%) | catalogued as rs369336277, COSV59536697; called by muse, mutect2, varscan2
- ZKSCAN3 | c.430C>T p.L144= | Silent (SNP) | VAF 8/176 reads (5%) | catalogued as COSV52852408; called by muse, mutect2
- CEP295 | c.5850+110G>C | Intron (SNP) | VAF 61/234 reads (26%) | catalogued as COSV57349017; called by muse, mutect2, varscan2
- FOXP1 | c.180+269G>C | Intron (SNP) | VAF 11/154 reads (7%) | catalogued as COSV100562296, COSV59517552; called by muse, mutect2
- NACA | c.70+3567C>G | Intron (SNP) | VAF 107/351 reads (30%) | catalogued as COSV63269852; called by muse, mutect2, varscan2
